CCDI case PBCCZT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8b24943d-6db7-4df9-b9c9-d31b093e8888

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant, uncertain whether primary or metastatic: ICD-O-3 morphology code: 8000/9; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.9 years (5,069 days).

Biospecimens (3 samples)
- Sample 0DP8NZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP8O3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP8O8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
